Somatic mutation profile of tumor specimen ALCH-B3DM-TTP1-A (aliquot ALCH-B3DM-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B3DM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.0 years (22,995 days).
Specimen ALCH-B3DM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4236ebab-2ad8-4c27-9330-5d9a10ed3618.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3DM-NB1-A (Blood Derived Normal), aliquot ALCH-B3DM-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d169ce8-d35f-41aa-95b8-e521acdd8bfb

The open-access MAF lists 445 somatic variants for this specimen: 301 protein-altering or splice-affecting, 93 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 258, Silent 93, Nonsense Mutation 24, Intron 22, RNA 17, Frame Shift Del 6, 5'UTR 5, Splice Region 5, Splice Site 4, Frame Shift Ins 3, 5'Flank 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH18A1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863225044, CM159181, COSV64662240; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP7B | c.2827G>A p.G943S | Missense Mutation (SNP) | VAF 68/537 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28942076, CM950115, CM994112, COSV54442282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 10/16 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50262762, COSV50266035; called by muse, mutect2, varscan2
- TP53 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 33/299 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.528C>G p.C176W | Missense Mutation (SNP) | VAF 37/179 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519980, COSV52687391, COSV52701599, COSV52735850, COSV99377692; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- UBE3A | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 28/710 reads (4%) | catalogued as rs587781219, CM1412832; ClinVar: pathogenic; called by muse, mutect2
- AASDHPPT | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 30/504 reads (6%) | catalogued as COSV53788797; called by muse, mutect2
- ABCC9 | c.3041G>T p.W1014L | Missense Mutation (SNP) | VAF 61/585 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); catalogued as rs74839837; called by muse, mutect2, varscan2
- ABHD18 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV66294421; called by muse, mutect2, varscan2
- ACOXL | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as rs778800133, COSV67733496; called by muse, mutect2
- ACTRT2 | c.22G>T p.D8Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV101007598; called by muse, mutect2, varscan2
- ALDH1L1 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs550440307, COSV56410533, COSV56414628; called by muse, mutect2, varscan2
- AMER2 | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.029); catalogued as COSV100766401; called by muse, varscan2
- BMP5 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 59/884 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63702148; called by muse, mutect2
- C1QL3 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs762617699; called by muse, mutect2, varscan2
- C1orf216 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV52050365; called by muse, mutect2, varscan2
- CARMIL2 | c.1199G>A p.R400K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.031); catalogued as rs1238344242; called by muse, mutect2, varscan2
- CCDC141 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs146458136; called by muse, mutect2
- CCDC80 | c.1646A>G p.E549G | Missense Mutation (SNP) | VAF 23/591 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as COSV99244970; called by muse, mutect2
- CDH26 | c.2393C>T p.S798F (on ENST00000348616 / NM_177980.4; = p.S131F on NM_021810.6) | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs766481135, COSV54847125; called by muse, mutect2, varscan2
- CNTNAP3 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 34/377 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV52664017, COSV52667704; called by muse, mutect2
- COL3A1 | c.4039G>A p.E1347K | Missense Mutation (SNP) | VAF 14/455 reads (3%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.446); catalogued as COSV58581838; called by muse, mutect2
- COL8A2 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs773423863, COSV57440666; called by muse, mutect2, varscan2
- CR1L | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 49/767 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV54328298; called by muse, mutect2
- CRB2 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1474833179, COSV63503082; called by muse, mutect2
- CRISPLD1 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 64/229 reads (28%) | catalogued as COSV51545364; called by muse, mutect2, varscan2
- CSMD1 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 23/422 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV68227675; called by muse, mutect2
- CSMD3 | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 71/686 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as COSV52233025, COSV99828356; called by muse, mutect2, varscan2
- CTNND2 | c.1333C>A p.L445M | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV58882509; called by muse, mutect2
- CTTNBP2 | c.343A>G p.M115V | Missense Mutation (SNP) | VAF 80/513 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV50486386; called by muse, mutect2, varscan2
- CUBN | c.9743C>T p.S3248F | Missense Mutation (SNP) | VAF 21/574 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV64720988; called by muse, mutect2
- CYP17A1 | c.995T>C p.I332T | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs772804570, CM101461; called by muse, mutect2, varscan2
- DNAH5 | c.5926G>T p.G1976* | Nonsense Mutation (SNP) | VAF 102/464 reads (22%) | catalogued as rs751690064; called by muse, mutect2, varscan2
- DNAI4 | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 37/612 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs989990588, COSV64020695; called by muse, mutect2
- DSC3 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 12/278 reads (4%) | catalogued as COSV100844363; called by muse, mutect2
- DUSP12 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV63411621; called by muse, mutect2
- EFR3A | c.2323C>T p.H775Y | Missense Mutation (SNP) | VAF 46/382 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs1346882971, COSV54453547; called by muse, mutect2, varscan2
- ERC1 | c.2809G>A p.E937K (on ENST00000360905 / NM_178040.4; = p.E909K on NM_178039.4) | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61698064; called by muse, mutect2, varscan2
- EVI5L | c.1456C>T p.L486F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.558); catalogued as rs199901235; called by muse, mutect2, varscan2
- EXOC4 | c.1871G>T p.R624M | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV54129094; called by muse, mutect2
- FAR1 | c.726A>T p.G242= | Splice Region (SNP) | VAF 24/294 reads (8%) | catalogued as rs1290119877; called by muse, mutect2
- GPC5 | c.494G>T p.R165I | Missense Mutation (SNP) | VAF 46/472 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV65597581, COSV65631670; called by muse, mutect2, varscan2
- HDAC9 | c.2096C>A p.S699* | Nonsense Mutation (SNP) | VAF 60/766 reads (8%) | catalogued as COSV67775720; called by muse, mutect2
- HECW2 | c.3365G>T p.G1122V | Missense Mutation (SNP) | VAF 59/439 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99647001; called by muse, mutect2, varscan2
- HGF | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 47/759 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55948049; called by muse, mutect2
- IL36A | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 110/584 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.799); catalogued as COSV99382135; called by muse, mutect2, varscan2
- JHY | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56219073; called by muse, mutect2, varscan2
- KHDRBS3 | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 29/532 reads (5%) | catalogued as COSV100878527; called by muse, mutect2
- KIF5B | c.2148C>G p.I716M | Missense Mutation (SNP) | VAF 34/401 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs1310599866; called by muse, mutect2
- LRFN5 | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 40/645 reads (6%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.04); catalogued as COSV53244373, COSV53262952; called by muse, mutect2
- LRP1B | c.10347C>G p.C3449W | Missense Mutation (SNP) | VAF 36/578 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67266413; called by muse, mutect2
- LRP6 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 93/404 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs770724799, COSV53794318; called by muse, mutect2, varscan2
- LRRC23 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 12/196 reads (6%) | catalogued as rs150183574; called by muse, mutect2
- MAP2K4 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62260612; called by muse, mutect2
- MDGA2 | c.290C>A p.T97K | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs768977988, COSV62077697; called by muse, mutect2, varscan2
- MOGAT2 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs773470557, COSV99549452; called by muse, mutect2, varscan2
- MON1B | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1024267863; called by muse, mutect2, varscan2
- MROH2B | c.2395G>T p.A799S | Missense Mutation (SNP) | VAF 26/596 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV68190079; called by muse, mutect2
- MTHFD1L | c.1549-1G>A p.X517_splice | Splice Site (SNP) | VAF 43/321 reads (13%) | catalogued as rs1460906883; called by muse, mutect2, varscan2
- MYH4 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs762459588, COSV55114424, COSV55124340; called by muse, mutect2
- NAIP | c.250del p.A84Lfs*8 | Frame Shift Del (DEL) | VAF 20/130 reads (15%) | catalogued as COSV52002007; called by mutect2, pindel, varscan2
- NBEA | c.4375G>A p.E1459K | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59765586; called by muse, mutect2
- NBPF6 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 52/800 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs576690061, COSV53996496; called by muse, mutect2
- NOTCH4 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs773306450, COSV100900814; called by muse, mutect2
- NPC1 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 27/504 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV52582323; called by muse, mutect2
- OR10A5 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV55053763; called by muse, mutect2
- OR13G1 | c.772C>A p.R258S | Missense Mutation (SNP) | VAF 24/443 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.035); catalogued as rs117404602, COSV62944488; called by muse, mutect2
- OR2V1 | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV61459295; called by muse, mutect2, varscan2
- OXR1 | c.1408C>T p.P470S (on ENST00000442977 / NM_001198532.1; = p.P469S on NM_018002.3) | Missense Mutation (SNP) | VAF 66/650 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1238523590; called by muse, mutect2
- PCDHB1 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV60631827; called by muse, mutect2, varscan2
- PHACTR2 | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 51/299 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59860154; called by muse, mutect2, varscan2
- PLSCR1 | c.463G>T p.G155W | Missense Mutation (SNP) | VAF 154/812 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100678338; called by muse, mutect2, varscan2
- POTEE | c.2422G>C p.A808P | Missense Mutation (SNP) | VAF 87/665 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV58239062; called by muse, mutect2, varscan2
- PPARGC1B | c.2180C>T p.A727V | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs770044041; called by muse, mutect2, varscan2
- PRDM10 | c.1606G>A p.G536R | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV58805631; called by muse, mutect2, varscan2
- PROKR2 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.972); catalogued as rs756998275, COSV54085498; called by muse, mutect2
- PROS1 | c.614G>A p.C205Y | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62399813; called by muse, mutect2
- PUS7 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 71/339 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775011521, COSV100708453; called by muse, mutect2, varscan2
- RBP3 | c.2330C>T p.A777V | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs145437524; called by muse, mutect2
- RGS4 | c.439A>T p.T147S | Missense Mutation (SNP) | VAF 25/541 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63358307; called by muse, mutect2
- ROBO1 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 22/220 reads (10%) | catalogued as COSV101459346; called by muse, mutect2
- ROBO3 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 24/355 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.135); catalogued as rs774489623, COSV67303128; called by muse, mutect2
- SCN4A | c.1135G>T p.G379W | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101438512; called by muse, mutect2, varscan2
- SEMA5A | c.1147C>A p.H383N | Missense Mutation (SNP) | VAF 44/820 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV66805256; called by muse, mutect2
- SETBP1 | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 14/392 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV104387893; called by muse, mutect2
- SETD1B | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310022642; called by muse, mutect2
- SHOX2 | c.532G>T p.G178C (on ENST00000441443 / NM_006884.3; = p.G202C on NM_003030.4) | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67463826; called by muse, mutect2, varscan2
- SIGLEC5 | c.900G>C p.E300D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.372); catalogued as COSV55783570; called by muse, mutect2, varscan2
- SLC22A15 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 44/522 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as rs1352370179; called by muse, mutect2
- SLC7A8 | c.1406G>T p.W469L | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.589); catalogued as COSV100328521; called by muse, mutect2, varscan2
- SOX6 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 34/678 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57039053, COSV57049882; called by muse, mutect2
- SYNM | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 106/812 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as rs782476697; called by muse, mutect2, varscan2
- TEKT3 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 42/999 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs532026904, COSV100107136; called by muse, mutect2
- TIMP1 | c.250G>T p.V84F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.483); catalogued as COSV54483664; called by muse, mutect2, varscan2
- TREM1 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 12/248 reads (5%) | catalogued as COSV55148936; called by muse, mutect2
- TRIM61 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs926000425; called by muse, varscan2
- TRPC6 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201368333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRRAP | c.9848G>T p.R3283L (on ENST00000359863 / NM_001244580.1; = p.R3254L on NM_003496.3) | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV104416843; called by muse, mutect2, varscan2
- TTN | c.17963T>G p.L5988W (on ENST00000591111; = p.L5061W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | PolyPhen probably damaging (0.98); catalogued as rs1267771409; called by muse, mutect2, varscan2
- TTN | c.7621G>T p.D2541Y (on ENST00000591111; = p.D2495Y on NM_003319.4) | Missense Mutation (SNP) | VAF 28/302 reads (9%) | PolyPhen probably damaging (0.988); catalogued as rs1462842843; called by muse, mutect2
- U2AF2 | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.764); catalogued as COSV100454029, COSV58276374; called by muse, mutect2, varscan2
- UGT2A2 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV54138113; called by muse, mutect2, varscan2
- USP2 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.813); catalogued as rs373153803; called by muse, mutect2, varscan2
- USP24 | c.2441A>G p.Y814C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs761788776, COSV53770181; called by muse, mutect2
- VCAM1 | c.279C>A p.Y93* | Nonsense Mutation (SNP) | VAF 24/356 reads (7%) | catalogued as COSV54118923; called by muse, mutect2
- WDR87 | c.4101G>C p.L1367F | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as COSV58194585; called by muse, mutect2
- WIZ | c.4045G>T p.A1349S (on ENST00000673675 / NM_001371589.1; = p.A254S on NM_021241.3) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.144); catalogued as COSV54607898; called by muse, mutect2, varscan2
- WNK4 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 100/447 reads (22%) | catalogued as rs974649105, COSV99891839; called by muse, mutect2, varscan2
- ZNF182 | c.254C>G p.P85R | Missense Mutation (SNP) | VAF 18/311 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.123); catalogued as rs782333958; called by muse, mutect2
- ZNF521 | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.129); catalogued as COSV64122723; called by muse, mutect2
- ZNF775 | c.219G>T p.R73S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs1354911842; called by muse, mutect2, varscan2
- ZNF790 | c.1427G>C p.R476T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV100764860, COSV63212405; called by muse, mutect2, varscan2
- ZSCAN1 | c.985T>A p.F329I | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56609278; called by muse, mutect2, varscan2
- A2M | c.2983C>A p.Q995K | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCB5 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ABCC5 | c.3100G>T p.V1034F | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- ABLIM2 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ADAM19 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.162); called by muse, mutect2
- ADAMTS16 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS17 | c.2678A>T p.Q893L | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ADGRG4 | c.1145A>G p.N382S | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.053); called by muse, mutect2
- AHNAK2 | c.13936T>C p.S4646P | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ALDH1A3 | c.737C>G p.S246C | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- AMD1 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2
- ANKRA2 | c.912G>T p.L304F | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ANKRD36C | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2
- ARID4A | c.1284G>T p.M428I | Missense Mutation (SNP) | VAF 40/450 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.713); called by muse, mutect2
- ASXL3 | c.4034C>G p.S1345C | Missense Mutation (SNP) | VAF 7/224 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ATG2A | c.1823G>T p.R608L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ATP2C1 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 79/406 reads (19%) | called by muse, mutect2, varscan2
- BPNT1 | c.728G>T p.C243F | Missense Mutation (SNP) | VAF 27/343 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- C12orf29 | c.788del p.K263Rfs*18 | Frame Shift Del (DEL) | VAF 22/99 reads (22%) | called by mutect2, pindel, varscan2
- C19orf25 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- C5orf22 | c.1262dup p.N421Kfs*29 | Frame Shift Ins (INS) | VAF 98/502 reads (20%) | called by mutect2, pindel, varscan2
- C6 | c.2033C>T p.T678I | Missense Mutation (SNP) | VAF 159/761 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CACNA2D1 | c.2081A>C p.N694T (on ENST00000356253 / NM_001366867.1; = p.N682T on NM_000722.4) | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.035); called by muse, mutect2
- CCDC168 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2
- CCDC88C | c.405G>C p.E135D | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.387); called by muse, mutect2
- CCNG2 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 22/257 reads (9%) | called by muse, mutect2
- CD300C | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 42/321 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CDH23 | c.5750A>T p.E1917V | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDYL | c.386C>T p.S129F (on ENST00000328908 / NM_001368125.1; = p.S75F on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/754 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2
- CEP131 | c.1625C>G p.S542C (on ENST00000269392 / NM_001319228.2; = p.S539C on NM_014984.4) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- CEP57L1 | c.963C>G p.D321E | Missense Mutation (SNP) | VAF 11/302 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.676); called by muse, mutect2
- CFAP46 | c.2183G>T p.G728V | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHID1 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2
- CHST15 | c.1542dup p.S515Ifs*32 | Frame Shift Ins (INS) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- CLTCL1 | c.4140C>A p.S1380R | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CMTR2 | c.1091del p.C364Lfs*9 | Frame Shift Del (DEL) | VAF 47/186 reads (25%) | called by mutect2, pindel, varscan2
- CNIH3 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL1A2 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 192/1031 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL1A2 | c.2390C>A p.P797H | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- COL22A1 | c.4162G>C p.E1388Q | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- COL24A1 | c.2564G>T p.G855V | Missense Mutation (SNP) | VAF 71/683 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.1675G>T p.D559Y | Missense Mutation (SNP) | VAF 80/622 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSTF3 | c.2134C>A p.Q712K | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); called by muse, mutect2
- CSTF3 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2
- CTNND2 | c.2205G>T p.E735D | Missense Mutation (SNP) | VAF 34/700 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); called by muse, mutect2
- DACH1 | c.1933C>A p.L645M (on ENST00000619232 / NM_001366712.1; = p.L391M on NM_004392.6) | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.08); called by muse, mutect2
- DCAF13 | c.1177C>T p.H393Y | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCDC1 | c.1055-1G>T p.X352_splice | Splice Site (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- DDX11 | c.2302G>A p.G768R (on ENST00000545668 / NM_152438.2; = p.G718R on NM_004399.3) | Missense Mutation (SNP) | VAF 51/375 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHRS9 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 57/365 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- DIPK1A | c.941G>C p.R314T | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- DLG2 | c.1285A>T p.T429S | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- DNAH2 | c.282G>A p.W94* | Nonsense Mutation (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- DPP7 | c.69C>G p.A23= | Splice Region (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- ECI2 | c.381G>T p.Q127H (on ENST00000380118 / NM_206836.3; = p.Q97H on NM_006117.2) | Missense Mutation (SNP) | VAF 29/720 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2
- ENOX1 | c.1754C>A p.A585D | Missense Mutation (SNP) | VAF 43/382 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ESF1 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAM171A1 | c.127G>C p.A43P | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- FAM186A | c.2186T>C p.V729A | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- FBN2 | c.413C>A p.S138* | Nonsense Mutation (SNP) | VAF 32/598 reads (5%) | called by muse, mutect2
- FSCB | c.778C>G p.P260A | Missense Mutation (SNP) | VAF 12/336 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.476); called by muse, mutect2
- FSIP2 | c.15415C>G p.L5139V | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.578); called by muse, mutect2
- GABRB2 | c.96T>A p.N32K | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2
- GLYATL3 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); called by muse, mutect2
- GRIN2B | c.2555del p.G852Vfs*32 | Frame Shift Del (DEL) | VAF 80/315 reads (25%) | called by mutect2, pindel, varscan2
- GRIN3A | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- GRXCR1 | c.645G>T p.L215F | Missense Mutation (SNP) | VAF 45/508 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2
- HEPACAM2 | c.598C>A p.Q200K (on ENST00000394468 / NM_001039372.4; = p.Q188K on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/822 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.091); called by muse, mutect2
- HEPH | c.2477T>A p.F826Y (on ENST00000343002; = p.F559Y on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- HMCN1 | c.13690G>T p.G4564C | Missense Mutation (SNP) | VAF 25/718 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HPSE2 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 57/489 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- HYDIN | c.7639G>T p.D2547Y | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- ICOS | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 59/518 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- IGKV3D-20 | c.225G>T p.R75S | Missense Mutation (SNP) | VAF 51/716 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); called by muse, mutect2
- IGSF1 | c.3976C>T p.Q1326* | Nonsense Mutation (SNP) | VAF 21/182 reads (12%) | called by muse, mutect2, varscan2
- IGSF10 | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 107/475 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ITGAV | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JARID2 | c.3602C>G p.S1201C | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- KCNH3 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KCTD3 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 26/367 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- KDM3B | c.361-1G>A p.X121_splice | Splice Site (SNP) | VAF 20/168 reads (12%) | called by muse, mutect2, varscan2
- KLHL12 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- KMT2D | c.9232G>A p.E3078K | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- KNG1 | c.974_976del p.E325_T326delinsA | In Frame Del (DEL) | VAF 56/502 reads (11%) | called by mutect2, pindel, varscan2
- KRTAP16-1 | c.949A>T p.S317C | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- LIPF | c.856A>C p.T286P | Missense Mutation (SNP) | VAF 41/335 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMTK2 | c.4261G>A p.D1421N | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC47 | c.1543G>C p.E515Q | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- LRRN3 | c.1281C>A p.S427R | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- M6PR | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 30/601 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2
- MAGI2 | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MALRD1 | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 68/696 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- MED13L | c.6501-7T>G | Splice Region (SNP) | VAF 34/560 reads (6%) | called by muse, mutect2
- MGAM2 | c.6221C>A p.T2074N | Missense Mutation (SNP) | VAF 17/452 reads (4%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- MORN1 | c.378C>A p.D126E | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- MSI1 | c.232C>A p.L78M | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MTOR | c.1265G>A p.S422N | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MUC17 | c.9037G>A p.D3013N | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- MYH1 | c.5037G>C p.E1679D | Missense Mutation (SNP) | VAF 18/474 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.436); called by muse, mutect2
- MYH1 | c.3444G>T p.E1148D | Missense Mutation (SNP) | VAF 77/575 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- MYH1 | c.1169T>A p.L390H | Missense Mutation (SNP) | VAF 13/318 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYL10 | c.280A>T p.T94S | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MZT2A | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.784); called by muse, varscan2
- NAV3 | c.4409C>T p.S1470F | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- NECAB1 | c.831G>C p.E277D | Missense Mutation (SNP) | VAF 13/413 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- NHEJ1 | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 99/673 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NOL3 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- NR5A1 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NSL1 | c.653A>C p.Q218P | Missense Mutation (SNP) | VAF 24/461 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- OBSCN | c.21505C>G p.Q7169E | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OLFM3 | c.106A>T p.R36W | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.253); called by muse, mutect2
- OR2A14 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 27/628 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.33); called by muse, mutect2
- OR5L2 | c.866T>A p.I289N | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR6C75 | c.829A>T p.T277S | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- PADI1 | c.995C>A p.A332D | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PCDHA4 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PCDHGB2 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2
- PDE6C | c.1089T>A p.N363K | Missense Mutation (SNP) | VAF 57/410 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PENK | c.138+7G>A | Splice Region (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- PEX10 | c.965T>G p.L322R | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PHACTR2 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKD1L1 | c.1831G>C p.E611Q | Missense Mutation (SNP) | VAF 24/596 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.548); called by muse, mutect2
- PKHD1L1 | c.2417C>T p.T806I | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2
- PLEKHD1 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PNLIPRP3 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 66/420 reads (16%) | called by muse, mutect2, varscan2
- POM121L2 | c.1895C>A p.S632Y | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- PRUNE1 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PSMA2 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 40/579 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTH2R | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PTPN22 | c.1171G>A p.A391T (on ENST00000359785 / NM_001193431.2; = p.A336T on NM_012411.5) | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2
- PTPRC | c.691A>C p.K231Q | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- RAD23B | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 46/209 reads (22%) | called by muse, mutect2, varscan2
- RARS2 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 21/477 reads (4%) | called by muse, mutect2
- RBP3 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 57/452 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHBG | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- RP1L1 | c.5512C>A p.P1838T | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- RRNAD1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 19/640 reads (3%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- RSL1D1 | c.1075A>T p.N359Y | Missense Mutation (SNP) | VAF 137/390 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RYR1 | c.5614A>T p.T1872S | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RYR3 | c.7483C>G p.L2495V (on ENST00000389232; = p.L2496V on NM_001036.6) | Missense Mutation (SNP) | VAF 11/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SALL1 | c.3560A>G p.N1187S | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- SEMA6D | c.805G>T p.V269F | Missense Mutation (SNP) | VAF 26/492 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SGIP1 | c.1615T>A p.Y539N | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.439); called by muse, mutect2
- SGIP1 | c.1940T>A p.V647E | Missense Mutation (SNP) | VAF 33/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- SHH | c.1136C>A p.P379H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SLC12A1 | c.867G>C p.E289D | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLC25A40 | c.19G>C p.G7R | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- SLC35C1 | c.700A>T p.N234Y | Missense Mutation (SNP) | VAF 55/308 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC44A5 | c.2078C>A p.T693K | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC6A19 | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 116/375 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLCO5A1 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- SLX4IP | c.413G>T p.R138I | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); called by muse, varscan2
- SNRNP27 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.694); called by muse, mutect2
- SP3 | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPAM1 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 26/862 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPATA31D1 | c.1873G>T p.E625* | Nonsense Mutation (SNP) | VAF 147/500 reads (29%) | called by muse, mutect2, varscan2
- SRGAP3 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- SUSD3 | c.162dup p.T55Dfs*29 | Frame Shift Ins (INS) | VAF 44/161 reads (27%) | called by mutect2, pindel, varscan2
- SYNE3 | c.1698C>G p.D566E | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.11); called by muse, mutect2
- TDRD6 | c.2679G>C p.Q893H | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2
- TEX43 | c.318A>G p.I106M | Missense Mutation (SNP) | VAF 99/420 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TEX47 | c.427T>C p.F143L | Missense Mutation (SNP) | VAF 24/347 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- THBS4 | c.371G>C p.R124P | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2
- THOP1 | c.510del p.K170Nfs*2 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel, varscan2
- TMTC4 | c.618G>A p.W206* (on ENST00000376234 / NM_001350577.2; = p.W225* on NM_032813.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- TNFRSF25 | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAT1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 68/472 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TRAV18 | c.158T>G p.F53C | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRAV8-3 | c.120G>C p.L40F | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRIO | c.2723A>T p.Q908L | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TRPA1 | c.1362C>A p.A454= | Splice Region (SNP) | VAF 195/895 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.100999G>A p.E33667K (on ENST00000591111; = p.E26243K on NM_003319.4) | Missense Mutation (SNP) | VAF 28/230 reads (12%) | PolyPhen benign (0.121); called by muse, mutect2, varscan2
- USP13 | c.2093-1G>A p.X698_splice | Splice Site (SNP) | VAF 28/138 reads (20%) | called by muse, mutect2
- VEZT | c.1740G>C p.K580N | Missense Mutation (SNP) | VAF 27/473 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2
- VIT | c.262_263del p.A88Cfs*8 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | called by pindel, varscan2
- XDH | c.507C>A p.C169* | Nonsense Mutation (SNP) | VAF 107/451 reads (24%) | called by muse, mutect2, varscan2
- ZFYVE1 | c.1138C>G p.Q380E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZMIZ1 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZMYM2 | c.3286G>T p.D1096Y | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2
- ZNF134 | c.492G>T p.E164D | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- ZNF169 | c.28A>G p.K10E | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF211 | c.1339C>T p.H447Y (on ENST00000347302 / NM_198855.4; = p.H460Y on NM_006385.5) | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF318 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ZNF423 | c.635C>A p.S212Y (on ENST00000563137 / NM_001379286.1; = p.S204Y on NM_015069.4) | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF585A | c.1177C>T p.Q393* (on ENST00000292841 / NM_001288800.2; = p.Q338* on NM_152655.3) | Nonsense Mutation (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- ZNF790 | c.1867G>C p.E623Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, varscan2
- ZPBP2 | c.489C>A p.F163L (on ENST00000348931 / NM_199321.3; = p.F141L on NM_198844.3) | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZSCAN5A | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- A2ML1 | c.3042G>A p.L1014= | Silent (SNP) | VAF 30/322 reads (9%) | catalogued as rs757380603; called by muse, mutect2
- AHNAK2 | c.11298G>T p.L3766= | Silent (SNP) | VAF 33/304 reads (11%) | called by muse, mutect2, varscan2
- AKAP13 | c.1393C>T p.L465= | Silent (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2, varscan2
- APBB2 | c.1608C>T p.A536= (on ENST00000295974 / NM_001166050.2; = p.A537= on NM_004307.2) | Silent (SNP) | VAF 11/218 reads (5%) | called by muse, mutect2
- ATG16L2 | c.675G>A p.L225= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as COSV58360831, COSV58361047; called by muse, mutect2, varscan2
- BEGAIN | c.828G>A p.A276= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs755135997; called by muse, varscan2
- BET1 | c.117G>A p.L39= | Silent (SNP) | VAF 20/457 reads (4%) | called by muse, mutect2
- BOP1 | c.2178C>T p.F726= | Silent (SNP) | VAF 20/361 reads (6%) | called by muse, mutect2
- C11orf49 | c.6G>A p.L2= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as COSV53571279; called by muse, mutect2
- C11orf87 | c.192G>A p.L64= | Silent (SNP) | VAF 43/387 reads (11%) | called by muse, mutect2, varscan2
- C5AR2 | c.933G>C p.L311= | Silent (SNP) | VAF 20/190 reads (11%) | called by muse, mutect2, varscan2
- C6 | c.2034T>C p.T678= | Silent (SNP) | VAF 164/772 reads (21%) | called by muse, mutect2, varscan2
- CACNA1E | c.141G>T p.A47= | Silent (SNP) | VAF 18/240 reads (8%) | catalogued as rs1357386518, COSV62386129; called by muse, mutect2
- CAPS | c.330C>T p.D110= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs200357068, COSV50387045; called by muse, mutect2, varscan2
- CCDC81 | c.765A>C p.S255= (on ENST00000445632 / NM_001156474.2; = p.S165= on NM_021827.4) | Silent (SNP) | VAF 21/133 reads (16%) | called by muse, mutect2, varscan2
- CDCP2 | c.306G>A p.L102= | Silent (SNP) | VAF 8/162 reads (5%) | catalogued as COSV61287092; called by muse, mutect2
- CEP170B | c.4684C>T p.L1562= (on ENST00000453495; = p.L1491= on NM_015005.3) | Silent (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- CHRNB2 | c.381C>T p.Y127= | Silent (SNP) | VAF 64/413 reads (15%) | catalogued as rs201024705, COSV63807947; called by muse, mutect2, varscan2
- CLIP4 | c.1857G>T p.G619= | Silent (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- COL9A3 | c.1530G>T p.T510= | Silent (SNP) | VAF 48/247 reads (19%) | catalogued as rs753631418; called by muse, mutect2, varscan2
- CPLX2 | c.90G>A p.A30= | Silent (SNP) | VAF 11/298 reads (4%) | catalogued as rs1342150504; called by muse, mutect2
- CRYGD | c.213C>A p.G71= | Silent (SNP) | VAF 28/262 reads (11%) | called by muse, mutect2, varscan2
- CSF3R | c.1329C>T p.H443= | Silent (SNP) | VAF 41/218 reads (19%) | called by muse, mutect2, varscan2
- DIO2 | c.597G>C p.L199= | Silent (SNP) | VAF 41/382 reads (11%) | catalogued as COSV101375944; called by muse, mutect2
- FANCI | c.3621C>G p.P1207= (on ENST00000310775 / NM_001376911.1; = p.P1147= on NM_018193.3) | Silent (SNP) | VAF 91/816 reads (11%) | catalogued as rs112582285; called by muse, mutect2, varscan2
- FER1L6 | c.1257G>C p.L419= | Silent (SNP) | VAF 17/445 reads (4%) | catalogued as COSV67549494; called by muse, mutect2
- FOXL3 | c.99C>A p.P33= | Silent (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- FSTL4 | c.363G>T p.L121= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as COSV99533377; called by muse, mutect2, varscan2
- FYB2 | c.180G>A p.K60= | Silent (SNP) | VAF 32/338 reads (9%) | catalogued as rs772431764; called by muse, mutect2
- FZD3 | c.1935C>T p.P645= | Silent (SNP) | VAF 40/534 reads (7%) | catalogued as rs745844816; called by muse, mutect2
- GBP5 | c.345C>A p.I115= | Silent (SNP) | VAF 60/393 reads (15%) | catalogued as COSV58592924; called by muse, mutect2, varscan2
- GUCY2C | c.2499C>T p.F833= | Silent (SNP) | VAF 18/200 reads (9%) | called by muse, mutect2
- HCN3 | c.619C>T p.L207= | Silent (SNP) | VAF 68/395 reads (17%) | called by muse, mutect2, varscan2
- HPGD | c.483C>T p.F161= | Silent (SNP) | VAF 25/872 reads (3%) | called by muse, mutect2
- HSD17B7 | c.369G>T p.L123= | Silent (SNP) | VAF 51/451 reads (11%) | catalogued as COSV99597787; called by muse, mutect2, varscan2
- IFT172 | c.916C>T p.L306= | Silent (SNP) | VAF 22/328 reads (7%) | called by muse, mutect2
- IGLV2-11 | c.21C>A p.L7= | Silent (SNP) | VAF 35/361 reads (10%) | called by muse, mutect2
- ITIH5 | c.1260C>T p.L420= | Silent (SNP) | VAF 32/604 reads (5%) | called by muse, mutect2
- KIF4B | c.204A>G p.A68= | Silent (SNP) | VAF 127/382 reads (33%) | called by muse, mutect2, varscan2
- KIF5C | c.1578G>A p.L526= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- LAIR1 | c.777C>G p.L259= | Silent (SNP) | VAF 17/159 reads (11%) | called by muse, mutect2
- LDB2 | c.432C>A p.I144= | Silent (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- MED12L | c.1797G>T p.L599= | Silent (SNP) | VAF 55/362 reads (15%) | called by muse, mutect2, varscan2
- MYO7A | c.3027C>T p.F1009= | Silent (SNP) | VAF 40/470 reads (9%) | called by muse, mutect2
- NBAS | c.4587C>G p.L1529= | Silent (SNP) | VAF 65/447 reads (15%) | called by muse, mutect2, varscan2
- NDRG1 | c.591G>A p.G197= | Silent (SNP) | VAF 41/289 reads (14%) | catalogued as rs377257830; called by muse, mutect2, varscan2
- NPHP1 | c.714A>C p.A238= | Silent (SNP) | VAF 79/824 reads (10%) | called by muse, mutect2
- OR12D3 | c.645C>A p.S215= | Silent (SNP) | VAF 16/327 reads (5%) | called by muse, mutect2
- OR2T12 | c.543G>T p.V181= | Silent (SNP) | VAF 65/482 reads (13%) | called by muse, mutect2, varscan2
- OR2T33 | c.468G>C p.L156= | Silent (SNP) | VAF 95/677 reads (14%) | called by muse, mutect2, varscan2
- OR8B4 | c.909C>T p.T303= | Silent (SNP) | VAF 10/74 reads (14%) | called by muse, varscan2
- PAX3 | c.123C>A p.L41= | Silent (SNP) | VAF 22/358 reads (6%) | catalogued as rs372340136, COSV99286741; called by muse, mutect2
- PCDHGA1 | c.1962C>G p.L654= | Silent (SNP) | VAF 18/426 reads (4%) | catalogued as rs912764298; called by muse, mutect2
- PCLO | c.7839G>T p.L2613= | Silent (SNP) | VAF 21/187 reads (11%) | called by muse, mutect2, varscan2
- PHF8 | c.420G>A p.L140= (on ENST00000357988 / NM_001184896.1; = p.L104= on NM_015107.3) | Silent (SNP) | VAF 8/246 reads (3%) | called by muse, mutect2
- PLCH1 | c.747G>C p.V249= (on ENST00000340059 / NM_001130960.2; = p.V261= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- PLXNA4 | c.1644C>T p.P548= | Silent (SNP) | VAF 42/229 reads (18%) | called by muse, mutect2, varscan2
- PNLIPRP3 | c.309G>A p.Q103= | Silent (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- POGZ | c.3537G>A p.Q1179= | Silent (SNP) | VAF 52/230 reads (23%) | called by muse, mutect2, varscan2
- PPP1R15B | c.1461T>C p.Y487= | Silent (SNP) | VAF 26/364 reads (7%) | catalogued as rs764864026; called by muse, mutect2
- PSAPL1 | c.930C>A p.S310= | Silent (SNP) | VAF 26/135 reads (19%) | called by muse, mutect2, varscan2
- PXDN | c.3033C>T p.G1011= | Silent (SNP) | VAF 19/423 reads (4%) | catalogued as rs1448505672, COSV53247484; called by muse, mutect2
- PYCR1 | c.846C>T p.I282= | Silent (SNP) | VAF 79/546 reads (14%) | called by muse, mutect2, varscan2
- RAG2 | c.1053T>A p.A351= | Silent (SNP) | VAF 58/569 reads (10%) | called by muse, mutect2, varscan2
- RASEF | c.1395C>T p.H465= | Silent (SNP) | VAF 13/216 reads (6%) | catalogued as rs373103397, COSV64588153; called by muse, mutect2
- RASSF7 | c.51C>T p.I17= | Silent (SNP) | VAF 31/275 reads (11%) | catalogued as rs1218320035; called by muse, mutect2, varscan2
- RFK | c.48C>T p.F16= | Silent (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- RFX6 | c.2775T>A p.A925= | Silent (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- RNF14 | c.150G>T p.V50= | Silent (SNP) | VAF 15/142 reads (11%) | called by muse, varscan2
- RPS6KA2 | c.2118T>G p.P706= | Silent (SNP) | VAF 37/127 reads (29%) | called by muse, mutect2, varscan2
- RTL9 | c.1080C>A p.P360= | Silent (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- RYR2 | c.5499C>A p.I1833= | Silent (SNP) | VAF 36/716 reads (5%) | catalogued as rs974906491, COSV63660786; ClinVar: likely benign; called by muse, mutect2
- SDK1 | c.4932C>T p.L1644= | Silent (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- SEMA6D | c.1332A>G p.E444= | Silent (SNP) | VAF 18/372 reads (5%) | called by muse, mutect2
- SLC6A13 | c.1254C>T p.V418= | Silent (SNP) | VAF 14/195 reads (7%) | called by muse, mutect2
- SRGAP2 | c.1692G>A p.L564= (on ENST00000624873 / NM_001170637.4; = p.L565= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/319 reads (5%) | catalogued as rs1174940490; called by muse, mutect2
- ST8SIA2 | c.957G>A p.P319= | Silent (SNP) | VAF 44/430 reads (10%) | catalogued as rs201615346; called by muse, mutect2, varscan2
- SYNE2 | c.5064C>G p.V1688= | Silent (SNP) | VAF 28/386 reads (7%) | called by muse, mutect2
- TEF | c.645C>A p.P215= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as COSV56748492; called by muse, mutect2
- TENM1 | c.3087G>C p.L1029= | Silent (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2, varscan2
- TERT | c.2859C>T p.S953= | Silent (SNP) | VAF 118/471 reads (25%) | called by muse, mutect2, varscan2
- TG | c.5529A>T p.P1843= | Silent (SNP) | VAF 58/900 reads (6%) | called by muse, mutect2
- TMEM121 | c.252C>T p.F84= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as rs782416609; called by muse, mutect2
- TP63 | c.879C>G p.P293= | Silent (SNP) | VAF 40/614 reads (7%) | catalogued as COSV99287691; called by muse, mutect2
- TRHDE | c.1260G>C p.L420= | Silent (SNP) | VAF 89/473 reads (19%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.4026A>T p.V1342= | Silent (SNP) | VAF 22/448 reads (5%) | called by muse, mutect2
- VCAM1 | c.1635G>T p.L545= | Silent (SNP) | VAF 49/252 reads (19%) | called by muse, mutect2, varscan2
- WDR87 | c.3756G>C p.L1252= | Silent (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- WIZ | c.4044G>T p.L1348= (on ENST00000673675 / NM_001371589.1; = p.L253= on NM_021241.3) | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- ZNF354C | c.1431C>T p.F477= | Silent (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- ZNF423 | c.636C>T p.S212= (on ENST00000563137 / NM_001379286.1; = p.S204= on NM_015069.4) | Silent (SNP) | VAF 61/217 reads (28%) | catalogued as COSV52184755, COSV52199011; called by muse, mutect2, varscan2
- ZNF592 | c.414C>T p.F138= | Silent (SNP) | VAF 44/210 reads (21%) | catalogued as rs1252416932, COSV55439543; called by muse, mutect2, varscan2
- ZNF804B | c.1509G>A p.K503= | Silent (SNP) | VAF 17/474 reads (4%) | called by muse, mutect2
- ABI3BP | c.1576+14075A>T | Intron (SNP) | VAF 42/659 reads (6%) | catalogued as COSV52536295; called by muse, mutect2
- AC109361.1 | n.3108G>T | RNA (SNP) | VAF 19/308 reads (6%) | called by muse, mutect2
- AC136777.1 | n.329A>T | RNA (SNP) | VAF 24/170 reads (14%) | called by muse, varscan2
- AGAP7P | n.1132C>T | RNA (SNP) | VAF 82/798 reads (10%) | called by muse, mutect2
- AL109984.1 | n.186+1258C>T | Intron (SNP) | VAF 45/209 reads (22%) | catalogued as COSV63752983; called by muse, mutect2, varscan2
- ANP32B | c.-19G>C | 5'UTR (SNP) | VAF 12/164 reads (7%) | catalogued as rs1414251910; called by muse, mutect2
- AP003393.1 | n.1053G>A | RNA (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- ASXL1 | c.57+905C>T | Intron (SNP) | VAF 49/415 reads (12%) | catalogued as rs757830631; called by muse, mutect2, varscan2
- BCAS3 | c.2075-4857G>T | Intron (SNP) | VAF 80/504 reads (16%) | catalogued as COSV66780103; called by muse, mutect2, varscan2
- C16orf70 | c.661+199G>C | Intron (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- CCDC144B | n.1890A>T | RNA (SNP) | VAF 63/337 reads (19%) | called by muse, mutect2, varscan2
- COA8 | c.123+178G>A | Intron (SNP) | VAF 13/216 reads (6%) | catalogued as rs1421841955; called by muse, mutect2
- EYS | c.1767-6680A>T | Intron (SNP) | VAF 54/1134 reads (5%) | called by muse, mutect2
- FCGR2A | c.86-14C>G | Intron (SNP) | VAF 36/405 reads (9%) | called by muse, mutect2
- GABRA1 | c.-15-18A>G | Intron (SNP) | VAF 69/499 reads (14%) | catalogued as rs1453797400; called by muse, mutect2, varscan2
- GRB10 | c.846+33G>C | Intron (SNP) | VAF 74/542 reads (14%) | catalogued as COSV60011812; called by muse, mutect2, varscan2
- GRM5 | c.661+38140C>T | Intron (SNP) | VAF 39/352 reads (11%) | catalogued as rs1301646605, COSV59609386, COSV59613263; called by muse, mutect2, varscan2
- HERC2P4 | n.394A>T | RNA (SNP) | VAF 40/273 reads (15%) | called by muse, mutect2, varscan2
- HNF1A | c.1623+41G>A | Intron (SNP) | VAF 10/127 reads (8%) | called by muse, mutect2
- HSP90AA4P | n.502G>T | RNA (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- HSPA1B | c.-175C>T | 5'UTR (SNP) | VAF 9/71 reads (13%) | catalogued as rs750832171, COSV65148544; called by muse, mutect2
- LINC01036 | n.112A>G | RNA (SNP) | VAF 25/244 reads (10%) | catalogued as rs1188613070; called by muse, mutect2, varscan2
- LINC01205 | n.157C>T | RNA (SNP) | VAF 41/238 reads (17%) | called by muse, mutect2, varscan2
- LLGL2 | c.2906-20A>T | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- MED24 | c.-26C>T | 5'UTR (SNP) | VAF 25/449 reads (6%) | catalogued as rs1370225251; called by muse, mutect2
- MMP26 | c.-145+92778G>T | Intron (SNP) | VAF 23/186 reads (12%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.961G>T | RNA (SNP) | VAF 89/755 reads (12%) | catalogued as rs776307739; called by muse, mutect2, varscan2
- NCDN | c.-75C>G | 5'UTR (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100357836; called by muse, mutect2
- NPIPB1P | n.417G>T | RNA (SNP) | VAF 59/546 reads (11%) | called by muse, mutect2, varscan2
- OSBPL2 | chr20:62233315 del G | 5'Flank (DEL) | VAF 15/81 reads (19%) | called by mutect2, pindel, varscan2
- PIGK | c.987-6990G>C | Intron (SNP) | VAF 97/714 reads (14%) | called by muse, mutect2, varscan2
- POLE2 | c.*22G>A | 3'UTR (SNP) | VAF 17/136 reads (13%) | catalogued as COSV99364966; called by muse, mutect2, varscan2
- POU2F1 | c.58+5689G>T | Intron (SNP) | VAF 18/572 reads (3%) | called by muse, mutect2
- PSG8 | chr19:42753330 A>T | 3'Flank (SNP) | VAF 116/427 reads (27%) | called by muse, mutect2, varscan2
- RNU6-713P | chr12:40550144 C>T | 3'Flank (SNP) | VAF 47/248 reads (19%) | called by muse, mutect2, varscan2
- RRM2B | c.48+165G>A | Intron (SNP) | VAF 26/327 reads (8%) | called by muse, mutect2
- SDHAP1 | n.1043C>T | RNA (SNP) | VAF 31/1024 reads (3%) | catalogued as rs1319934910; called by muse, mutect2
- SPATA31D5P | n.1074A>G | RNA (SNP) | VAF 22/288 reads (8%) | catalogued as rs749478205; called by muse, mutect2
- SSPOP | n.14876G>C | RNA (SNP) | VAF 31/186 reads (17%) | called by muse, mutect2, varscan2
- SSX6P | n.130G>A | RNA (SNP) | VAF 14/451 reads (3%) | called by muse, mutect2
- SVIL2P | n.1822G>T | RNA (SNP) | VAF 105/442 reads (24%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.*33C>T | 3'UTR (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- TMTC1 | c.939-26597C>A | Intron (SNP) | VAF 36/436 reads (8%) | called by muse, mutect2
- TRAPPC9 | chr8:140458365 C>A | 5'Flank (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- TRIM29 | c.1705-1148G>T | Intron (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- TRIM74 | chr7:72969781 G>A | 5'Flank (SNP) | VAF 14/207 reads (7%) | called by muse, varscan2
- UBTFL2 | n.394G>A | RNA (SNP) | VAF 193/1229 reads (16%) | catalogued as rs769357719; called by muse, mutect2, varscan2
- VOPP1 | c.55-17494G>T | Intron (SNP) | VAF 34/192 reads (18%) | called by muse, mutect2, varscan2
- XKR4 | c.-5G>T | 5'UTR (SNP) | VAF 31/171 reads (18%) | called by muse, mutect2, varscan2
- ZMAT5 | c.127+14G>T | Intron (SNP) | VAF 28/278 reads (10%) | called by muse, mutect2, varscan2
- ZNF655 | c.136+1195C>A | Intron (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
